CCDI case PBBYXM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/b9f8620b-ed58-45b5-837d-48b55e991d6d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Other specified parts of female genital organs; Age at diagnosis: 3.1 years (1,129 days).

Biospecimens (3 samples)
- Sample 0DL1T2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL1T9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL1TO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
